Somatic mutation profile of tumor specimen TCGA-G9-6373-01A (aliquot TCGA-G9-6373-01A-11D-1786-08) from TCGA case TCGA-G9-6373, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.1 years (24,887 days).
Specimen TCGA-G9-6373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05774c45-236d-489f-8418-a7ee832aec22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6373-10A (Blood Derived Normal), aliquot TCGA-G9-6373-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/948606a8-b376-4a16-b952-36f884360fae

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 16, Silent 5, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTBL2 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.267); catalogued as COSV70661455; called by muse, mutect2, varscan2
- BAZ2B | c.1907A>G p.D636G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs763785582, COSV58604456; called by muse, mutect2, varscan2
- BCL6 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); catalogued as rs142220629; called by muse, mutect2, varscan2
- COL22A1 | c.3343A>G p.N1115D | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs764676655, COSV57345044; called by muse, mutect2, varscan2
- DCLRE1A | c.399A>G p.I133M | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63749102; called by muse, mutect2
- DST | c.15059G>A p.S5020N (on ENST00000361203 / NM_001374722.1; = p.S2608N on NM_015548.5) | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as COSV55024263; called by muse, mutect2, varscan2
- DSTYK | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV65687155; called by muse, mutect2, varscan2
- FAM234B | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.805); catalogued as COSV52195652; called by muse, mutect2, varscan2
- GPR32 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as rs1176984459, COSV54514949; called by muse, mutect2, varscan2
- GUCY1A2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748015731, COSV56483067; called by muse, mutect2, varscan2
- HOOK3 | c.1606T>C p.S536P | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV56884342; called by muse, mutect2, varscan2
- HPGD | c.498G>T p.A166= | Splice Region (SNP) | VAF 43/98 reads (44%) | catalogued as COSV56663253, COSV99640324; called by muse, mutect2, varscan2
- LAMC1 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.11); catalogued as COSV51140513, COSV51151308; called by muse, mutect2, varscan2
- LRP1B | c.3231A>C p.K1077N | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.976); catalogued as COSV67243151; called by muse, mutect2, varscan2
- MED13L | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56123776; called by muse, mutect2, varscan2
- SSH1 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765955367, COSV58457803; called by muse, mutect2, varscan2
- ZFYVE16 | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV62016272; called by muse, mutect2, varscan2
- KMT2C | c.3797_3798insT p.T1267Nfs*54 | Frame Shift Ins (INS) | VAF 34/124 reads (27%) | called by mutect2, pindel*, varscan2
- APBA1 | c.405C>T p.A135= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV55231210; called by muse, mutect2, varscan2
- CRIM1 | c.945C>T p.G315= | Silent (SNP) | VAF 68/334 reads (20%) | catalogued as rs372559618; called by muse, mutect2, varscan2
- INAVA | c.1044C>T p.S348= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV66257034; called by muse, mutect2, varscan2
- KLHDC7B | c.1296G>A p.A432= (on ENST00000395676; = p.A1073= on NM_138433.5) | Silent (SNP) | VAF 57/184 reads (31%) | catalogued as COSV67464863; called by muse, mutect2, varscan2
- PLCH1 | c.2364C>T p.N788= (on ENST00000340059 / NM_001130960.2; = p.N800= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs1433147675, COSV58194417; called by muse, mutect2, varscan2
